Somatic mutation profile of tumor specimen BA2280D (aliquot aq-BA2280D) from BEATAML1.0 case 2044, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,519 days).
Specimen BA2280D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cba8713a-736b-4034-9588-3ef36d9009de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2892D (Solid Tissue Normal), aliquot aq-BA2892D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f63f34b2-9c0f-4788-ac03-e96f046de28b

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 3'UTR 1, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 16/70 reads (23%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- COL4A2 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64627883; called by muse, mutect2, varscan2
- CYP2S1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs768488156; called by muse, mutect2, varscan2
- HEG1 | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772002458, COSV60759766; called by muse, mutect2, varscan2
- MYH14 | c.3613C>T p.R1205C | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1277975602; called by mutect2, varscan2
- ATG2A | c.3630G>T p.E1210D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2
- CEBPA | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- KCNB1 | c.2465G>A p.G822E | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by mutect2, varscan2
- KIR3DL3 | c.973C>A p.L325M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- RANBP17 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by mutect2, varscan2
- RTL1 | c.2623T>C p.F875L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SSU72 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.159); called by muse, mutect2
- TET2 | c.4653_4669delinsGAC p.H1551Qfs*22 | Frame Shift Del (DEL) | VAF 15/114 reads (13%) | called by pindel, varscan2*
- ACTL8 | c.957C>T p.H319= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs780320203; called by muse, mutect2, varscan2
- SUGCT | c.27A>C p.A9= | Silent (SNP) | VAF 22/62 reads (35%) | called by muse, varscan2
- TIAL1 | c.93G>A p.Q31= | Silent (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- HDAC4 | c.*9C>T | 3'UTR (SNP) | VAF 50/96 reads (52%) | catalogued as rs765249256; called by muse, varscan2
